Somatic mutation profile of tumor specimen TCGA-NA-A4QV-01A (aliquot TCGA-NA-A4QV-01A-11D-A28R-08) from TCGA case TCGA-NA-A4QV, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basal cell carcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IB; Age at diagnosis: 72.2 years (26,379 days).
Specimen TCGA-NA-A4QV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73383030-dc78-4ce0-918a-e5a6f60a7f1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4QV-10A (Blood Derived Normal), aliquot TCGA-NA-A4QV-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af188aa5-eb5d-48da-bb7d-4a6cb3de3527

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 49/56 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BTRC | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.835); catalogued as rs752077302, COSV64561145; called by muse, mutect2, varscan2
- DSC1 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104377535; called by muse, mutect2
- LCE2C | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 129/267 reads (48%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs199701090, COSV64228551; called by muse, mutect2, varscan2
- MYBPC1 | c.1564C>A p.P522T (on ENST00000550270 / NM_206820.2; = p.P547T on NM_002465.4) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100638190; called by muse, mutect2, varscan2
- PGAM1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs979317271, COSV100602400; called by muse, mutect2, varscan2
- PML | c.1910G>C p.R637P | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as COSV51451382; called by muse, mutect2, varscan2
- POTEF | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as COSV62544265; called by muse, mutect2, varscan2
- RASGRF2 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.296); catalogued as rs780471153, COSV54122290; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | PolyPhen possibly damaging (0.557); catalogued as COSV60348199; called by muse, mutect2, varscan2
- TBC1D25 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65124809; called by muse, mutect2, varscan2
- ULK1 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376434906, COSV58855496; called by muse, mutect2, varscan2
- ZFP36L1 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 105/194 reads (54%) | catalogued as COSV60546166; called by muse, mutect2, varscan2
- ARFGEF1 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC88B | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPB1 | c.2022G>A p.M674I | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DNAH8 | c.7511A>C p.K2504T | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPY19L2 | c.1881C>G p.I627M | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, varscan2
- DYNC1H1 | c.2795A>G p.D932G | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- F2 | c.11_14dup p.G6Pfs*16 | Frame Shift Ins (INS) | VAF 37/45 reads (82%) | called by mutect2, pindel, varscan2
- HCFC1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HSPB1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSS | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR4D9 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR6A2 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFAS | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SIPA1L3 | c.3516C>G p.Y1172* | Nonsense Mutation (SNP) | VAF 334/594 reads (56%) | called by muse, mutect2, varscan2
- SYCP2 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM26 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 28/909 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WFDC8 | c.627del p.K210Rfs*25 | Frame Shift Del (DEL) | VAF 51/133 reads (38%) | called by mutect2, pindel, varscan2
- ZNF407 | c.775T>A p.L259M | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AL021546.1 | c.153C>T p.Y51= | Silent (SNP) | VAF 78/157 reads (50%) | catalogued as rs747925967; called by muse, mutect2, varscan2
- DNAJA2 | c.852C>T p.F284= | Silent (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- DPP10 | c.2016C>T p.S672= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs369883174; called by muse, mutect2, varscan2
- DSC3 | c.1473C>T p.N491= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs138254140; called by muse, mutect2, varscan2
- GABPA | c.1254C>T p.V418= | Silent (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- MAG | c.1815G>T p.R605= | Silent (SNP) | VAF 109/183 reads (60%) | called by muse, mutect2, varscan2
- NAV3 | c.630G>A p.S210= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs751011496, COSV57120195; called by muse, mutect2, varscan2
- NBPF15 | c.1098T>C p.D366= | Silent (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- STN1 | c.591C>T p.G197= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs772601033; called by muse, mutect2, varscan2
- TACC2 | c.114G>T p.T38= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- TMEM132A | c.141G>A p.P47= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs778452382; called by muse, mutect2, varscan2
- TMEM132E | c.1719G>A p.P573= (on ENST00000321639; = p.P663= on NM_001304438.2) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs774827026; called by muse, varscan2
- DTNA | c.1094+1367C>T | Intron (SNP) | VAF 24/55 reads (44%) | catalogued as rs772119129, COSV99313376; called by muse, mutect2, varscan2
